Somatic mutation profile of tumor specimen 0DPQQK from CCDI case PBCDHX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.3 years (854 days).
Specimen 0DPQQK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b0cbfe8-a0b1-4664-b93c-a3d647cd5eaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPQQ9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/336884f0-6b8e-4d3e-8d74-d851b0d6432b

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA1D | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65242361; called by muse, mutect2
- ARHGAP39 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 14/369 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1332156834, COSV52769887; called by muse, mutect2
- CAD | c.4760T>C p.I1587T | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370372528; called by muse, mutect2, varscan2
- LRRC43 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 36/488 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs753792682, COSV60289071; called by muse, mutect2
- AC011525.1 | n.651G>C | RNA (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
